Surgical pathology report (de-identified scan), TCGA case TCGA-FP-7735, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-FP-7735-01A (Primary Tumor).

[page 1 of 4]
FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

A. - C.) STOMACH, PANCREATIC LYMPH NODE, GALLBLADDER, TOTAL GASTRECTOMY, CHOLECYSTECTOMY AND LYMPH NODE BIOPSY:

- Adenocarcinoma, moderately differentiated.
- Tumor size: 3.0 cm.
- Tumor invades muscularis propria.
- Surgical margins free of tumor, closest margin radial at 8 mm.
- Eighteen lymph nodes, no tumor seen (0/18).
- Chronic cholecystitis.

PATHOLOGIC TUMOR STAGING SYNOPSIS:

Type and grade: Adenocarcinoma, grade 2.

Primary tumor: pT2.

Regional lymph nodes: pN0 (0/18 lymph nodes).

Distant metastasis: pMX.

Pathologic stage: IB.

Lymphovascular invasion: Not identified.

Margin status: R0, negative.

Tumor Staging Information

Stomach (Data derived from current specimen. Staging in accordance with or modified from AJCC Cancer Staging Handbook, 7th Ed, and CAP protocol, [REDACTED])

[page 2 of 4]
Procedure:	Total gastrectomy.
Specimen type:	Total gastrectomy.
Other organs received:	Pancreatic lymph node, gallbladder.
Tumor features:	
Tumor site:	Stomach, tumor is 3.0 cm from the gastro-esophageal junction with the epicenter of the tumor being 4.5 cm from the GE junction.
Tumor size:	3.0 cm.
Histologic type:	Adenocarcinoma.
Histologic grade:	Moderately differentiated, G2.
Microscopic extent of tumor:	Tumor invades muscularis propria.
Lymphovascular invasion:	Not identified.
Treatment effect:	N/A.
Lymph nodes:	Eighteen lymph nodes, no tumor seen (0/18).
Margin evaluation:	
Proximal margin:	Negative, 3.5 cm.
Distal margin:	Negative, greater than 10 cm.
Omental (radial) margin:	Negative, 0.8 cm.
Deep margin:	N/A.
Pathologic tumor staging descriptors:	
Primary tumor:	pT2.
Regional lymph nodes:	pN0 (0/18 lymph nodes).
Distant metastasis:	pMX.
Margin status:	R0, negative.
Pathologic stage:	IB.
Additional pathologic findings:	Gastrointestinal stromal tumor (GIST), chronic inactive gastritis with intestinal metaplasia and esophagitis consistent with gastroesophageal reflux.
Comment:	N/A.

[page 3 of 4]
FINAL SURGICAL PATHOLOGY REPORT

Source of Specimen:

- A. Lymph node;Pancreatic Lymph Node
- B. Gallbladder
- C. Total Gastrectomy

Intraoperative Diagnosis:

C. Total gastrectomy: Proximal margin negative on frozen section. The intraoperative interpretation(s) was/were performed and rendered at

Gross Description:

A. Part A is a pancreatic lymph node. Received is a 1.4 x 1.0 x 0.5 cm lymph node candidate. Sectioning demonstrates a rubbery to firm, semi-congested, deep red and light gray cut surface. The lymph node is entirely submitted in A1, bisected.

B. Part B is a gallbladder. Received in formalin is an intact gallbladder measuring 10.2 x 2.3 x 2.2 cm. The serosa is glistening, tan-green. The cystic duct margin is crimped with surgical hardware, and removed to reveal an obvious patent lumen. The wall is 0.1-0.2 cm, and the lumen contains viscous green bile without calculi; no calculi present within the container. The dome of the fundus is thickened up to 0.4 cm with multiple cysts. The mucosa is velvety and dark green with gross unusual changes suggestive of neoplasia. Representative sections submitted for microscopic evaluation in B1.

C. Part C is a total gastrectomy. Initially received in the fresh state for frozen section analysis and tumor bank studies, is a total gastrectomy; the greater curvature is 21.7 cm and the left curvature 15.4 cm. The distal margin of resection is 3.2 cm in diameter, terminating 1.0 cm distal to the pyloric orifice. Perigastric fat is associated with the lesser and greater curvatures, extends out to 3.5 and 3.0 cm, respectively. The gastric serosa is hyperemic, light pink to congested purple-red, initially without palpable mass. The stomach is opened along the greater curvature to reveal a fungating, dusky red tumor mass up to 3.0 x 3.0 cm, oriented 3.0 cm distal to the EG junction, and 3.5 cm from the proximal margin of resection. The tumor overlies the posterior gastric wall within 1.5 cm of the lesser curvature. Sectioning through the tumor demonstrates tumor involvement of the muscularis propria. The tumor is 7 mm from the radial margin and overlying fat (C3, C4). The proximal surgical margin is trimmed and submitted for frozen section analysis. Representation of viable tumor and adjacent gastric tissue is submitted for tumor bank studies. The remainder of the gastric mucosa demonstrates prominent rugae, with the transition into the antrum showing increased hemorrhagic congestion. No additional ulcerations, mass lesions, or unusual areas of induration suggestive of additional neoplastic change or tumor involvement. Examination of the perigastric fat associated with the left curvature reveals eleven lymph node candidates, ranging from 0.15 cm to 1.0 cm. The perigastric fat associated with the greater curvature reveals five lymph node candidates, 0.2-0.4 cm.

Cassette summary: C1) proximal surgical margin of resection, frozen section, C2) distal margin of

[page 4 of 4]
FINAL SURGICAL PATHOLOGY REPORT

resection, C3-C8) tumor, C9-C10) perpendicular representation through EG junction and gastric mucosa adjacent to tumor, C11) gastric fundus and antrum represented, three pieces, C12) five lymph node candidates, lesser curvature, C13) five lymph node candidates, lesser curvature, C14) large lymph node, bisected, lesser curvature, C15) five lymph node candidates, greater curvature.

Microscopic Description:

A. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. Immunohistochemistry was performed with adequate control for OSCAR keratin and no metastatic tumor cells are identified.

B. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

C. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. Immunohistochemistry was performed with adequate control for Helicobacter, Desmin, MSA, smooth muscle myosin, S100, SMA, CD117 and OSCAR keratin. No Helicobacter organisms are identified by immunohistochemistry. There is a small bland spindle cell proliferation in the muscularis propria seen on block C9. The spindle cells are positive for CD117 and focally weakly positive for desmin, SMA, MSA, smooth muscle myosin and negative for OSCAR keratin and S-100. The immunohistochemistry staining pattern is consistent with a gastrointestinal stromal tumor (GIST).

Source: NCI Genomic Data Commons file ca9ea54d-a488-445e-b5af-fc7da5d14f4c (TCGA-FP-7735.1DBAE53F-F151-4CC5-81BF-F684DFDB71CA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).